Somatic mutation profile of tumor specimen 58a92726-4d1f-4e44-8938-52b97d (aliquot 58a92726-4d1f-4e44-8938-52b97d_D6) from CPTAC case 05CO029, project CPTAC-2 (Colon — Adenomas and Adenocarcinomas). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IIA.
Specimen 58a92726-4d1f-4e44-8938-52b97d: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0e8dda62-3a6f-4ea1-b5b8-cfbcdb71ed3f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 848bb071-7372-4b79-abfe-9728da (Blood Derived Normal), aliquot 848bb071-7372-4b79-abfe-9728da_D1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7eb57eed-1f73-4195-8f1b-b9acc1825061

The open-access MAF lists 146 somatic variants for this specimen: 86 protein-altering or splice-affecting, 34 silent, 26 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 74, Silent 34, Intron 15, Nonsense Mutation 8, 3'UTR 7, Splice Region 3, RNA 3, Splice Site 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.4216C>T p.Q1406* | Nonsense Mutation (SNP) | VAF 96/437 reads (22%) | hotspot (GDC flag); catalogued as rs587782518, CM023011, COSV57321535; ClinVar: pathogenic; called by muse, mutect2, varscan2
- DUSP16 | c.1447C>T p.R483* | Nonsense Mutation (SNP) | VAF 49/139 reads (35%) | hotspot (GDC flag); catalogued as COSV53806110; called by muse, mutect2, varscan2
- TRPS1 | c.2722C>T p.R908* (on ENST00000220888 / NM_001330599.2; = p.R921* on NM_014112.5 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 148/676 reads (22%) | catalogued as rs751565386, CM154764, COSV55227212; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ANKS1B | c.2813G>A p.R938H (on ENST00000547776 / NM_152788.4; = p.R164H on NM_020140.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 54/155 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59114711; called by muse, mutect2, varscan2
- APC | c.4028C>A p.S1343Y | Missense Mutation (SNP) | VAF 134/573 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.08); catalogued as CD067521, COSV57371246; called by muse, mutect2, varscan2
- BNC2 | c.2158C>T p.R720W | Missense Mutation (SNP) | VAF 202/882 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.412); catalogued as rs751961896, COSV66148194; called by muse, varscan2
- BRD1 | c.2540G>A p.R847Q (on ENST00000216267 / NM_001349940.1; = p.R978Q on NM_001304808.3) | Missense Mutation (SNP) | VAF 119/356 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.805); catalogued as rs375422499; called by muse, mutect2, varscan2
- BSN | c.10708G>A p.D3570N | Missense Mutation (SNP) | VAF 16/74 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs779949346; called by muse, mutect2, varscan2
- CAMK1G | c.8G>A p.R3Q | Missense Mutation (SNP) | VAF 31/143 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.494); catalogued as rs749190689; called by muse, mutect2, varscan2
- CBS | c.352G>A p.V118M | Missense Mutation (SNP) | VAF 65/516 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as rs763385546, COSV61445103; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CDR2L | c.992C>A p.A331D | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.491); catalogued as rs1368915495; called by muse, mutect2, varscan2
- DNAH17 | c.9262G>A p.G3088S | Missense Mutation (SNP) | VAF 40/210 reads (19%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.828); catalogued as rs771803250; called by muse, mutect2, varscan2
- ELFN2 | c.370C>T p.R124* | Nonsense Mutation (SNP) | VAF 44/464 reads (9%) | catalogued as COSV68746133; called by muse, mutect2
- ELP1 | c.1703C>A p.S568* | Nonsense Mutation (SNP) | VAF 58/581 reads (10%) | catalogued as COSV65896812; called by muse, mutect2
- ERFE | c.985G>A p.V329M | Missense Mutation (SNP) | VAF 61/252 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs770547903; called by muse, mutect2, varscan2
- ESAM | c.334C>T p.R112W | Missense Mutation (SNP) | VAF 52/482 reads (11%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.91); catalogued as rs371439555; called by muse, mutect2, varscan2
- ESYT3 | c.2287C>T p.R763C | Missense Mutation (SNP) | VAF 28/223 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as rs554792770, COSV101272627; called by muse, mutect2, varscan2
- GABBR1 | c.2767C>T p.R923C | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs772112428; called by muse, mutect2, varscan2
- GIT1 | c.1414C>T p.R472W | Missense Mutation (SNP) | VAF 45/461 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as rs749589787; called by muse, mutect2, varscan2
- GLIS1 | c.1742C>T p.A581V | Missense Mutation (SNP) | VAF 14/126 reads (11%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0); catalogued as rs755556848, COSV56542948, COSV56543019; called by mutect2, varscan2
- GRK3 | c.1321G>A p.G441R | Missense Mutation (SNP) | VAF 7/66 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as rs200199764; called by muse, mutect2, varscan2
- GSTM2 | c.111C>T p.D37= | Splice Region (SNP) | VAF 26/173 reads (15%) | catalogued as rs1270397771; called by muse, mutect2, varscan2
- HSDL2 | c.800C>T p.P267L | Missense Mutation (SNP) | VAF 18/126 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.308); catalogued as COSV52714067; called by muse, mutect2, varscan2
- KIF5B | c.2702G>A p.R901H | Missense Mutation (SNP) | VAF 74/281 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as rs1426703960, COSV56652597; called by muse, mutect2, varscan2
- LCN1 | c.464G>A p.R155H | Missense Mutation (SNP) | VAF 14/142 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.541); catalogued as rs143361927; called by muse, mutect2
- LRRC45 | c.568C>T p.R190W | Missense Mutation (SNP) | VAF 24/236 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs900751872; called by muse, mutect2, varscan2
- LRRIQ1 | c.4420-1G>T p.X1474_splice | Splice Site (SNP) | VAF 8/71 reads (11%) | catalogued as COSV101280405; called by muse, mutect2, varscan2
- MACROH2A2 | c.44G>A p.R15H | Missense Mutation (SNP) | VAF 24/190 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1424339350; called by muse, mutect2, varscan2
- MFSD5 | c.119G>A p.R40Q | Missense Mutation (SNP) | VAF 73/484 reads (15%) | SIFT tolerated (0.29); PolyPhen benign (0.001); catalogued as rs1320325029; called by muse, mutect2, varscan2
- MMP8 | c.164G>A p.G55D | Missense Mutation (SNP) | VAF 48/572 reads (8%) | SIFT tolerated (0.76); PolyPhen benign (0.001); catalogued as rs763868356; called by muse, mutect2
- MYO16 | c.4121C>T p.A1374V | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT tolerated, low confidence (0.53); PolyPhen benign (0.001); catalogued as rs377541193; called by mutect2, varscan2
- NADSYN1 | c.1665C>G p.I555M | Missense Mutation (SNP) | VAF 46/224 reads (21%) | SIFT tolerated (0.15); PolyPhen benign (0.015); catalogued as rs1277207991; called by muse, mutect2, varscan2
- NELL1 | c.1069C>T p.R357* | Nonsense Mutation (SNP) | VAF 63/235 reads (27%) | catalogued as rs371903884, COSV54255758; called by muse, mutect2, varscan2
- PCDHA3 | c.1342G>A p.V448M | Missense Mutation (SNP) | VAF 158/745 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.953); catalogued as rs782192647, COSV63538755; called by muse, mutect2, varscan2
- PLOD2 | c.892G>A p.V298I | Missense Mutation (SNP) | VAF 26/214 reads (12%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.939); catalogued as rs947167279, COSV51462298, COSV99283280; called by muse, mutect2, varscan2
- PTGFR | c.758C>T p.A253V | Missense Mutation (SNP) | VAF 22/133 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.108); catalogued as rs145816454, COSV66114518; called by muse, mutect2, varscan2
- RAD54L | c.2062C>T p.R688C | Missense Mutation (SNP) | VAF 237/767 reads (31%) | SIFT tolerated (0.08); PolyPhen benign (0.418); catalogued as rs1185739428, COSV58442287; called by muse, mutect2, varscan2
- RASAL3 | c.811C>T p.R271C | Missense Mutation (SNP) | VAF 30/285 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.015); catalogued as COSV100640338; called by muse, mutect2, varscan2
- RYR1 | c.5962G>A p.A1988T | Missense Mutation (SNP) | VAF 67/589 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as rs763360938, COSV62098686; called by muse, mutect2, varscan2
- SLITRK5 | c.805C>T p.R269C | Missense Mutation (SNP) | VAF 42/524 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV61523559; called by muse, mutect2
- SOX9 | c.337A>G p.M113V | Missense Mutation (SNP) | VAF 115/330 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as CM103412, COSV55425734; called by muse, mutect2, varscan2
- SPAG4 | c.247C>T p.R83W | Missense Mutation (SNP) | VAF 14/77 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.65); catalogued as rs760835000; called by muse, mutect2, varscan2
- SPTY2D1 | c.1459C>T p.R487W | Missense Mutation (SNP) | VAF 63/304 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.698); catalogued as rs139020346, COSV100311550; called by muse, mutect2, varscan2
- TADA2A | c.176A>G p.H59R | Missense Mutation (SNP) | VAF 10/82 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs374099682; called by muse, mutect2
- THSD7B | c.3760G>T p.G1254W (on ENST00000272643; = p.G1252W on NM_001316349.2) | Missense Mutation (SNP) | VAF 17/139 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as COSV55732433; called by muse, mutect2, varscan2
- TP53 | c.154C>T p.Q52* | Nonsense Mutation (SNP) | VAF 71/262 reads (27%) | catalogued as COSV52734084, COSV53134595; called by muse, mutect2, varscan2
- TRIM73 | c.23T>C p.L8P | Missense Mutation (SNP) | VAF 46/686 reads (7%) | SIFT tolerated, low confidence (0.57); PolyPhen benign (0); catalogued as rs73702636; called by muse, mutect2
- WDR1 | c.652G>A p.G218R (on ENST00000382452; = p.G78R on NM_005112.5) | Missense Mutation (SNP) | VAF 75/501 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs904508193; called by muse, mutect2, varscan2
- ZBED6CL | c.694C>A p.H232N | Missense Mutation (SNP) | VAF 19/101 reads (19%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0.055); catalogued as rs551547810; called by mutect2, varscan2
- ZBTB11 | c.179C>T p.A60V | Missense Mutation (SNP) | VAF 29/242 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.403); catalogued as rs774623364; called by muse, mutect2, varscan2
- ZNF132 | c.532G>A p.A178T | Missense Mutation (SNP) | VAF 36/415 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0.005); catalogued as rs759276688, COSV54234103; called by muse, mutect2
- ZNF701 | c.65C>T p.S22L | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT tolerated, low confidence (0.22); PolyPhen possibly damaging (0.519); catalogued as rs1232866950; called by muse, mutect2
- ARHGAP21 | c.3368G>A p.W1123* | Nonsense Mutation (SNP) | VAF 30/74 reads (41%) | called by muse, mutect2, varscan2
- ARMC5 | c.123C>A p.S41R | Missense Mutation (SNP) | VAF 20/122 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.264); called by mutect2, varscan2
- ATAD5 | c.231A>T p.Q77H | Missense Mutation (SNP) | VAF 14/90 reads (16%) | SIFT tolerated (0.6); PolyPhen benign (0.145); called by muse, mutect2, varscan2
- ATP6V0D2 | c.80T>C p.L27P | Missense Mutation (SNP) | VAF 19/96 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); called by mutect2, varscan2
- BTBD8 | c.4777C>G p.P1593A (on ENST00000636805 / NM_001376131.1; = p.P1080A on NM_015237.4) | Missense Mutation (SNP) | VAF 25/114 reads (22%) | SIFT tolerated (0.32); PolyPhen benign (0.437); called by muse, mutect2, varscan2
- CFAP65 | c.3791T>A p.I1264N | Missense Mutation (SNP) | VAF 74/257 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.485); called by muse, mutect2, varscan2
- CX3CL1 | c.921G>T p.W307C | Missense Mutation (SNP) | VAF 97/294 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- DNAH17 | c.10022C>A p.S3341Y | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by mutect2, varscan2
- FAM160A1 | c.1763C>A p.S588Y | Missense Mutation (SNP) | VAF 108/313 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.819); called by muse, mutect2, varscan2
- FN1 | c.6770A>C p.N2257T (on ENST00000359671 / NM_001365524.2; = p.N2226T on NM_002026.4) | Missense Mutation (SNP) | VAF 49/382 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GPRC5C | c.608C>T p.T203I (on ENST00000652232; = p.T158I on NM_018653.4) | Missense Mutation (SNP) | VAF 56/594 reads (9%) | SIFT tolerated (0.4); PolyPhen benign (0.003); called by muse, mutect2
- GPRC6A | c.2539T>A p.S847T | Missense Mutation (SNP) | VAF 56/305 reads (18%) | SIFT tolerated (0.11); PolyPhen benign (0.067); called by muse, mutect2, varscan2
- HEPH | c.3168G>A p.M1056I (on ENST00000343002; = p.M789I on NM_014799.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/146 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HSPA9 | c.1797C>A p.F599L | Missense Mutation (SNP) | VAF 39/240 reads (16%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.302); called by muse, mutect2, varscan2
- IL18 | c.325A>G p.T109A | Missense Mutation (SNP) | VAF 10/83 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.581); called by muse, mutect2, varscan2
- IL2 | c.388G>A p.E130K | Missense Mutation (SNP) | VAF 4/54 reads (7%) | SIFT tolerated (0.52); PolyPhen benign (0); called by muse, mutect2
- LTBP4 | c.3763G>A p.D1255N (on ENST00000308370 / NM_001042544.1; = p.D1218N on NM_003573.2) | Missense Mutation (SNP) | VAF 21/161 reads (13%) | SIFT tolerated (0.22); PolyPhen benign (0.056); called by muse, mutect2, varscan2
- MCF2 | c.1549G>C p.V517L | Missense Mutation (SNP) | VAF 11/151 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.855); called by muse, mutect2
- MEX3C | c.791C>T p.T264M | Missense Mutation (SNP) | VAF 21/124 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MYO7A | c.6449C>T p.T2150I | Missense Mutation (SNP) | VAF 34/338 reads (10%) | SIFT tolerated (0.42); PolyPhen benign (0.003); called by muse, mutect2
- NAIP | c.307A>G p.I103V | Missense Mutation (SNP) | VAF 24/268 reads (9%) | SIFT tolerated (0.62); PolyPhen benign (0.116); called by muse, mutect2
- NLRP8 | c.1782G>T p.L594F | Missense Mutation (SNP) | VAF 35/340 reads (10%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.598); called by muse, mutect2, varscan2
- NRIP1 | c.1088A>T p.K363M | Missense Mutation (SNP) | VAF 41/240 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- PCDHB6 | c.1194C>A p.F398L | Missense Mutation (SNP) | VAF 101/391 reads (26%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.249); called by muse, mutect2, varscan2
- RAB11FIP5 | c.870C>T p.G290= | Splice Region (SNP) | VAF 7/92 reads (8%) | called by muse, mutect2
- RFPL4A | c.530A>T p.K177M | Missense Mutation (SNP) | VAF 136/1178 reads (12%) | SIFT tolerated (0.12); PolyPhen benign (0.007); called by muse, mutect2
- RNF169 | c.113C>A p.A38D | Missense Mutation (SNP) | VAF 11/80 reads (14%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.179); called by muse, varscan2
- SCLY | c.1104C>A p.N368K (on ENST00000651534; = p.N360K on NM_016510.7) | Missense Mutation (SNP) | VAF 20/183 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.82); called by muse, mutect2, varscan2
- STON1 | c.1734G>T p.W578C | Missense Mutation (SNP) | VAF 64/352 reads (18%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.858); called by muse, varscan2
- TFAP2E | c.1060G>A p.E354K | Missense Mutation (SNP) | VAF 16/126 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- TUSC3 | c.902C>A p.A301E | Missense Mutation (SNP) | VAF 34/296 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- TXK | c.284C>A p.P95H | Missense Mutation (SNP) | VAF 25/234 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- USP15 | c.1616A>G p.N539S (on ENST00000280377 / NM_001351159.2; = p.N510S on NM_006313.3 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 13/192 reads (7%) | SIFT tolerated (0.74); PolyPhen benign (0.229); called by muse, mutect2
- VWCE | c.1963C>T p.L655= | Splice Region (SNP) | VAF 39/150 reads (26%) | called by muse, mutect2, varscan2
- ALDH1A2 | c.1020C>T p.S340= | Silent (SNP) | VAF 95/656 reads (14%) | catalogued as rs114347273; called by muse, mutect2, varscan2
- BMP6 | c.441C>T p.N147= | Silent (SNP) | VAF 43/322 reads (13%) | catalogued as rs373910078, COSV51673299; called by muse, mutect2, varscan2
- CA9 | c.1290G>A p.A430= | Silent (SNP) | VAF 34/259 reads (13%) | catalogued as rs754134463, COSV61405278; called by muse, mutect2, varscan2
- CNTNAP5 | c.852G>A p.T284= | Silent (SNP) | VAF 41/185 reads (22%) | catalogued as rs370887782; called by muse, mutect2, varscan2
- COL5A1 | c.825C>T p.Y275= | Silent (SNP) | VAF 43/460 reads (9%) | catalogued as rs771253587, COSV65666294; ClinVar: likely benign; called by muse, mutect2
- CSMD1 | c.870A>T p.L290= | Silent (SNP) | VAF 31/112 reads (28%) | called by muse, mutect2, varscan2
- DCDC1 | c.3759G>A p.P1253= (on ENST00000597505 / NM_001367979.1; = p.P360= on NM_020869.3) | Silent (SNP) | VAF 49/156 reads (31%) | catalogued as rs142454340; called by muse, mutect2, varscan2
- DNAI4 | c.2256C>T p.D752= | Silent (SNP) | VAF 29/233 reads (12%) | catalogued as rs145210188; called by muse, mutect2, varscan2
- EML1 | c.1428G>A p.S476= | Silent (SNP) | VAF 8/72 reads (11%) | catalogued as rs536030370; called by muse, mutect2, varscan2
- ERBB4 | c.3459T>C p.P1153= | Silent (SNP) | VAF 51/404 reads (13%) | catalogued as COSV100726968; called by muse, mutect2, varscan2
- FAM90A10P | c.753C>G p.L251= | Silent (SNP) | VAF 114/527 reads (22%) | catalogued as rs1231935635; called by muse, mutect2, varscan2
- GPR158 | c.2616G>A p.S872= | Silent (SNP) | VAF 53/306 reads (17%) | catalogued as rs138351980; called by muse, mutect2, varscan2
- HFE | c.903G>A p.P301= | Silent (SNP) | VAF 83/674 reads (12%) | catalogued as rs372856303, COSV100352727; called by muse, mutect2, varscan2
- HSH2D | c.1002C>T p.N334= | Silent (SNP) | VAF 17/119 reads (14%) | catalogued as rs753804748; called by muse, mutect2, varscan2
- ITIH5 | c.2493C>T p.S831= | Silent (SNP) | VAF 83/240 reads (35%) | catalogued as rs770780812, COSV53675418; called by muse, mutect2, varscan2
- KCNH7 | c.1644C>T p.G548= | Silent (SNP) | VAF 55/235 reads (23%) | catalogued as COSV59792751; called by muse, mutect2, varscan2
- MAGEL2 | c.1080G>A p.A360= | Silent (SNP) | VAF 20/158 reads (13%) | catalogued as rs1191799957; called by muse, mutect2, varscan2
- MECOM | c.1689G>A p.E563= (on ENST00000468789 / NM_001105078.4; = p.E751= on NM_004991.4) | Silent (SNP) | VAF 173/310 reads (56%) | called by muse, mutect2, varscan2
- MECOM | c.378C>T p.D126= (on ENST00000468789 / NM_001105078.4; = p.D314= on NM_004991.4) | Silent (SNP) | VAF 49/294 reads (17%) | catalogued as rs1218341508; called by muse, mutect2, varscan2
- MYO1E | c.1821C>T p.V607= | Silent (SNP) | VAF 44/336 reads (13%) | catalogued as rs375000696; called by muse, mutect2, varscan2
- NOG | c.678C>T p.S226= | Silent (SNP) | VAF 31/323 reads (10%) | called by muse, mutect2, varscan2
- NSD1 | c.2058T>C p.Y686= | Silent (SNP) | VAF 111/412 reads (27%) | called by muse, mutect2, varscan2
- NXNL1 | c.54C>T p.D18= | Silent (SNP) | VAF 81/380 reads (21%) | catalogued as rs779889890, COSV100112052; called by muse, mutect2, varscan2
- OR5AC2 | c.843G>A p.T281= | Silent (SNP) | VAF 20/235 reads (9%) | catalogued as rs201602794, COSV62279983; called by muse, mutect2
- PLCB1 | c.231C>T p.H77= | Silent (SNP) | VAF 30/103 reads (29%) | catalogued as rs773937907, COSV62040242; ClinVar: likely benign; called by muse, mutect2, varscan2
- PLXNB2 | c.1458C>T p.C486= | Silent (SNP) | VAF 22/234 reads (9%) | catalogued as rs755441363; called by muse, mutect2
- PRPF3 | c.120G>A p.K40= | Silent (SNP) | VAF 18/103 reads (17%) | called by muse, mutect2, varscan2
- RBPJL | c.1320G>A p.A440= | Silent (SNP) | VAF 45/444 reads (10%) | catalogued as COSV59214440; called by muse, mutect2
- RPAP1 | c.3546C>G p.L1182= | Silent (SNP) | VAF 67/362 reads (19%) | called by muse, mutect2, varscan2
- RYR2 | c.13305C>A p.T4435= | Silent (SNP) | VAF 58/198 reads (29%) | catalogued as COSV63684187; called by mutect2, varscan2
- SPSB4 | c.135G>A p.A45= | Silent (SNP) | VAF 18/125 reads (14%) | catalogued as rs773533519; called by muse, varscan2
- TPO | c.744C>G p.T248= | Silent (SNP) | VAF 80/599 reads (13%) | called by muse, mutect2, varscan2
- TRIM73 | c.24G>A p.L8= | Silent (SNP) | VAF 46/690 reads (7%) | catalogued as rs73702637; called by muse, mutect2
- ZSCAN18 | c.1524G>A p.A508= | Silent (SNP) | VAF 6/74 reads (8%) | catalogued as rs1294657450, COSV53733278; called by muse, mutect2
- ABCA13 | c.12070+60T>G | Intron (SNP) | VAF 49/464 reads (11%) | called by muse, mutect2, varscan2
- AC136628.2 | n.690A>G | RNA (SNP) | VAF 13/262 reads (5%) | called by muse, mutect2
- AC244517.10 | c.36-8799G>A | Intron (SNP) | VAF 77/605 reads (13%) | catalogued as rs782229291, COSV73145128; called by muse, mutect2, varscan2
- AP000755.1 | n.278C>T | RNA (SNP) | VAF 6/32 reads (19%) | called by muse, mutect2
- COPS7A | c.*11G>A | 3'UTR (SNP) | VAF 43/176 reads (24%) | catalogued as rs748551302; called by muse, varscan2
- DLG4 | c.787+17C>A | Intron (SNP) | VAF 21/112 reads (19%) | called by muse, mutect2, varscan2
- FBXL13 | c.496-5535C>T | Intron (SNP) | VAF 90/387 reads (23%) | catalogued as rs374080339; called by muse, mutect2, varscan2
- FBXL18 | c.2000+1156G>A | Intron (SNP) | VAF 56/227 reads (25%) | catalogued as rs748155336, COSV101212086; called by muse, mutect2, varscan2
- LINC00917 | n.1564+1523C>T | Intron (SNP) | VAF 24/220 reads (11%) | catalogued as rs774528420; called by muse, mutect2, varscan2
- MAP2 | c.455-2001G>A | Intron (SNP) | VAF 19/122 reads (16%) | catalogued as rs895782635; called by muse, mutect2, varscan2
- MAU2 | c.*225G>A | 3'UTR (SNP) | VAF 65/498 reads (13%) | catalogued as rs532744009; called by muse, mutect2, varscan2
- MCOLN2 | c.*16G>T | 3'UTR (SNP) | VAF 26/146 reads (18%) | catalogued as rs1276879769, COSV99393883; called by muse, mutect2, varscan2
- MLIP | c.613-11863C>T | Intron (SNP) | VAF 54/509 reads (11%) | catalogued as rs1412613126; called by muse, mutect2, varscan2
- OFCC1 | n.2277G>A | RNA (SNP) | VAF 9/165 reads (5%) | catalogued as rs967186711; called by muse, mutect2
- RBM46 | c.1403-1045G>T | Intron (SNP) | VAF 15/77 reads (19%) | called by muse, mutect2, varscan2
- SCFD1 | c.1554-176C>T | Intron (SNP) | VAF 8/54 reads (15%) | called by muse, mutect2, varscan2
- SCUBE1 | c.*5346G>A | 3'UTR (SNP) | VAF 19/358 reads (5%) | called by muse, mutect2
- SLC22A4 | c.393+233A>G | Intron (SNP) | VAF 44/254 reads (17%) | catalogued as rs1465449848; called by muse, mutect2, varscan2
- SMOC1 | c.-42G>A | 5'UTR (SNP) | VAF 19/67 reads (28%) | catalogued as rs1421590051; called by muse, mutect2, varscan2
- SZRD1 | c.*93G>T | 3'UTR (SNP) | VAF 26/139 reads (19%) | called by muse, mutect2, varscan2
- TK2 | c.31+119G>C | Intron (SNP) | VAF 37/261 reads (14%) | catalogued as rs1219771104; called by muse, mutect2, varscan2
- TPI1 | c.*250_*251del | 3'UTR (DEL) | VAF 84/650 reads (13%) | catalogued as rs1163707622; called by pindel, varscan2
- TRIM9 | c.1604-3998G>A | Intron (SNP) | VAF 18/86 reads (21%) | catalogued as COSV100030209; called by muse, mutect2, varscan2
- TRPV6 | c.1639+14C>A | Intron (SNP) | VAF 34/259 reads (13%) | called by muse, mutect2, varscan2
- TTN | c.10360+4893C>A | Intron (SNP) | VAF 77/536 reads (14%) | catalogued as rs1204686501, COSV100632397; called by mutect2, varscan2
- ZNF71 | c.*2C>T | 3'UTR (SNP) | VAF 42/166 reads (25%) | catalogued as rs141286207; called by muse, mutect2, varscan2
